Gene-level copy-number profile of tumor specimen HTMCP-02-06-01157-01B from CGCI case HTMCP-02-06-01157, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung.
Specimen HTMCP-02-06-01157-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bbce9ca8-a04c-41c4-9b16-25c441a516cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-06-01157-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/d6059d6a-254a-4a3e-bb99-eee970c8dd6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 672; copy number 1: 22,118; copy number 2: 30,533; copy number 3: 4,135; copy number 4: 1,333; copy number 6: 10; copy number 7: 17; copy number 8: 1; copy number 9: 7; copy number 26: 10; copy number 29: 1; copy number 30: 52; copy number 32: 12; copy number 33: 6; copy number 38: 4.

Homozygous deletions (total copy number 0; autosomes only): 160 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,965,227, 9 genes (within-gene range 0–1): LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr3:195,650,146–195,739,964, 6 genes (within-gene range 0–1): AC233280.2, AC233280.1, MUC20-OT1, SDHAP2, MIR570, SMBD1P.
- chr7:6,952,625–7,104,482, 4 genes: AC079804.3, MIR3683, AC092104.1, Y_RNA.
- chr9:21,058,771–22,455,740, 55 genes: IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:40,130,921–40,642,117, 18 genes: AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2.
- chr9:60,914,407–61,642,494, 15 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr10:48,050,282–48,119,455, 2 genes: BMS1P7, PTPN20CP.
- chr16:33,938,337–33,950,420, 3 genes: IGHV3OR16-7, AC140658.4, IGHV3OR16-16.
- chr17:18,390,153–18,551,705, 16 genes (within-gene range 0–1): AL353997.5, TBC1D3P4, LINC02076, KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr21:7,744,962–8,680,934, 28 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 120 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:20,296,637–20,777,038, 8 genes, copy number 7: AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1.
- chr7:36,512,941–36,724,549, 1 gene, copy number 6 (within-gene range 4–6): AOAH.
- chr7:36,734,004–37,449,249, 9 genes, copy number 6 (within-gene range 4–6): AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2, ELMO1, MIR1200, ELMO1-AS1, RPS17P13.
- chr7:54,933,699–55,678,490, 15 genes, copy number 7–9: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1.
- chr7:56,991,888–57,009,149, 1 gene, copy number 7: TNRC18P3.
- chr7:62,275,361–62,275,678, 1 gene, copy number 8: AC128676.1.
- chr14:35,362,232–41,149,309, 85 genes, copy number 26–38 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,774. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
